Somatic mutation profile of tumor specimen TCGA-77-8140-01A (aliquot TCGA-77-8140-01A-11D-2244-08) from TCGA case TCGA-77-8140, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.8 years (24,415 days).
Specimen TCGA-77-8140-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d35db9cc-9ccf-4f3f-b700-fa4de65e3901.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8140-10A (Blood Derived Normal), aliquot TCGA-77-8140-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/153d5ab4-690a-46bf-a83c-73fa81cacf68

The open-access MAF lists 408 somatic variants for this specimen: 314 protein-altering or splice-affecting, 83 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 279, Silent 83, Frame Shift Del 13, Nonsense Mutation 11, Intron 5, Splice Site 5, 3'UTR 3, Splice Region 2, RNA 2, Translation Start Site 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLA | c.979C>A p.Q327K | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28935491, CM051537, CM930336, COSV99516224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 19/59 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1911+1G>C p.X637_splice | Splice Site (SNP) | VAF 19/74 reads (26%) | catalogued as COSV99684872; called by muse, mutect2, varscan2
- ACTR6 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549932412, COSV99498522; called by muse, mutect2, varscan2
- ADAM18 | c.1973G>T p.G658V | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV99695064; called by muse, mutect2, varscan2
- ADAM29 | c.2108C>G p.P703R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV63661544; called by muse, mutect2, varscan2
- ADAMTS12 | c.159C>A p.H53Q | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.51); catalogued as COSV100710421; called by muse, mutect2, varscan2
- ADGRA2 | c.2791C>A p.P931T | Missense Mutation (SNP) | VAF 58/446 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1242316929, COSV55102720, COSV99604774; called by muse, mutect2, varscan2
- ADGRE3 | c.479C>A p.T160K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as COSV99505918; called by muse, mutect2, varscan2
- ADGRG4 | c.4483C>A p.P1495T | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1206158683, COSV99794673; called by muse, mutect2, varscan2
- AGXT2 | c.1451C>A p.A484E | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV99183720; called by muse, mutect2
- AIFM3 | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100104328; called by muse, mutect2, varscan2
- AJUBA | c.1019A>G p.K340R | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as COSV99400855; called by muse, mutect2, varscan2
- AOAH | c.582A>C p.P194= | Splice Region (SNP) | VAF 26/78 reads (33%) | catalogued as COSV99332313; called by muse, mutect2, varscan2
- APEX2 | c.1547G>T p.R516M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.934); catalogued as COSV100238079; called by muse, mutect2, varscan2
- APLN | c.224T>C p.M75T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100278246; called by muse, mutect2
- APOC3 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV99922589; called by muse, mutect2, varscan2
- AQP9 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 77/284 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV99582696; called by muse, mutect2, varscan2
- ARHGAP19 | c.1247A>T p.K416M | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100363037; called by muse, mutect2, varscan2
- ARL13A | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.108); catalogued as COSV100879002; called by muse, mutect2, varscan2
- ATL3 | c.619-2A>G p.X207_splice | Splice Site (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100219742; called by muse, mutect2, varscan2
- ATP4B | c.220C>G p.Q74E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375485094; called by muse, mutect2, varscan2
- ATP6AP1 | c.1189C>G p.L397V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100870659; called by muse, mutect2, varscan2
- ATR | c.5998G>T p.G2000C | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV63388628; called by muse, mutect2, varscan2
- ATRX | c.4839G>T p.L1613F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100970220; called by muse, mutect2, varscan2
- ATRX | c.3090G>C p.K1030N | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.036); catalogued as rs1557138210, COSV100970221; called by muse, varscan2
- BCAR1 | c.2474G>T p.G825V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV99366155; called by muse, mutect2, varscan2
- BMP8B | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100735466; called by muse, mutect2
- BPIFB1 | c.287A>T p.Q96L | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV99487233; called by muse, mutect2, varscan2
- BPIFB2 | c.304T>A p.F102I | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.364); catalogued as COSV99401221; called by muse, mutect2, varscan2
- BRDT | c.2775+2T>G p.X925_splice | Splice Site (SNP) | VAF 37/119 reads (31%) | catalogued as COSV100746191; called by muse, mutect2, varscan2
- BRPF3 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1205623596, COSV100325644; called by muse, mutect2, varscan2
- C3 | c.4240G>C p.D1414H | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836225; called by muse, mutect2, varscan2
- C3 | c.3156G>C p.G1052= | Splice Region (SNP) | VAF 4/12 reads (33%) | catalogued as rs1301971690, COSV99836228; called by muse, mutect2, varscan2
- C3AR1 | c.1367C>A p.A456E | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV50820557, COSV99368186; called by muse, mutect2, varscan2
- CADPS2 | c.1570A>G p.S524G | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs1180717427, COSV100461235; called by muse, mutect2, varscan2
- CASK | c.1882G>C p.D628H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100586884, COSV100586947; called by muse, mutect2, varscan2
- CASKIN1 | c.609C>G p.D203E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.759); catalogued as COSV100623860; called by muse, mutect2, varscan2
- CCAR1 | c.3139G>T p.V1047L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99770703; called by muse, mutect2, varscan2
- CCDC59 | c.413A>G p.Q138R | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99810541; called by muse, mutect2, varscan2
- CCSER1 | c.106A>T p.S36C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV100388726; called by muse, mutect2, varscan2
- CD248 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV60937820; called by muse, mutect2, varscan2
- CDH13 | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV99223487; called by muse, mutect2, varscan2
- CDH8 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100180001; called by muse, mutect2, varscan2
- CEP104 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV65512291; called by muse, mutect2, varscan2
- CFAP61 | c.1601A>T p.Y534F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV55621757, COSV99843714; called by muse, mutect2, varscan2
- CHD7 | c.6867G>T p.M2289I | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101418056; called by muse, mutect2, varscan2
- CHKA | c.333C>G p.F111L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as COSV99694051; called by muse, mutect2, varscan2
- CHRM2 | c.752G>T p.S251I | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as COSV100280870; called by muse, mutect2
- CNKSR3 | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101527227; called by mutect2, varscan2
- CNOT1 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as COSV100408652; called by muse, mutect2
- COG2 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1480893180, COSV100794627; called by muse, mutect2, varscan2
- COL6A6 | c.1518C>G p.I506M | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100649961, COSV62032399; called by muse, mutect2, varscan2
- CPA2 | c.1016C>A p.S339Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV55979972; called by muse, mutect2, varscan2
- CPB1 | c.334A>G p.T112A | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99294132; called by muse, mutect2, varscan2
- CPN2 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100102919; called by muse, mutect2, varscan2
- CPNE3 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.378); catalogued as COSV52204666, COSV52204997; called by muse, mutect2
- CRAMP1 | c.3002C>G p.T1001S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99245709; called by muse, mutect2, varscan2
- CSKMT | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as rs935850025, COSV100649025; called by muse, mutect2, varscan2
- CST5 | c.416G>C p.C139S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100489578; called by muse, mutect2, varscan2
- CWH43 | c.1370C>G p.T457R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99892976; called by muse, mutect2, varscan2
- CYLC2 | c.226T>C p.W76R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766100136, COSV100872388; called by muse, mutect2, varscan2
- CYP4F11 | c.1330C>G p.R444G | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99930683; called by muse, mutect2
- DACH2 | c.1262C>G p.P421R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100912691, COSV64180571; called by muse, mutect2, varscan2
- DCAF12L1 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100948134; called by muse, mutect2, varscan2
- DDX18 | c.1748A>G p.Y583C | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs780962053, COSV99604391; called by muse, mutect2, varscan2
- DDX53 | c.357C>A p.Y119* | Nonsense Mutation (SNP) | VAF 40/119 reads (34%) | catalogued as COSV100028723; called by muse, mutect2, varscan2
- DGAT2L6 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as COSV100283911; called by mutect2, varscan2
- DHX38 | c.1673G>A p.G558E | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99194211; called by muse, mutect2, varscan2
- DLG3 | c.1284G>C p.R428S (on ENST00000374360 / NM_021120.4; = p.R91S on NM_020730.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV99529264; called by muse, varscan2
- DMD | c.3683C>A p.A1228D | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV100818552; called by muse, mutect2, varscan2
- DMD | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.06); catalogued as COSV55897295, COSV99920246; called by muse, mutect2, varscan2
- DMRT2 | c.1362G>C p.K454N | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as COSV99425949; called by muse, mutect2, varscan2
- DNAH10 | c.2353G>A p.D785N (on ENST00000409039; = p.D724N on NM_207437.3) | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs771482050, COSV68996163; called by muse, mutect2, varscan2
- DNAH2 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); catalogued as rs968120016, COSV50013131; called by muse, mutect2, varscan2
- DNAH2 | c.7780G>T p.D2594Y | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV101209076; called by muse, mutect2, varscan2
- DNAH8 | c.9566G>T p.C3189F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100543749; called by muse, mutect2, varscan2
- DPP8 | c.2524A>G p.S842G (on ENST00000341861 / NM_001320875.2; = p.S726G on NM_017743.6) | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV100202160; called by muse, mutect2, varscan2
- DXO | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV100514593; called by muse, mutect2, varscan2
- DYRK4 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV50537819; called by muse, mutect2, varscan2
- ENOX1 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 92/238 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV99815323; called by muse, mutect2, varscan2
- EOLA2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100778035; called by muse, mutect2, varscan2
- EPB41L2 | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100440337; called by muse, mutect2, varscan2
- EPHA7 | c.2874G>T p.M958I | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.667); catalogued as COSV100993383; called by muse, mutect2, varscan2
- EPHB6 | c.1594G>C p.D532H | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV100844169; called by muse, mutect2, varscan2
- EPS8 | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV55537480, COSV99842772; called by muse, mutect2, varscan2
- ERCC2 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV99676125; called by muse, mutect2
- ESYT3 | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100004760, COSV56680202; called by muse, mutect2, varscan2
- EXO1 | c.819C>A p.N273K | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100799650; called by muse, mutect2, varscan2
- F5 | c.3145C>T p.H1049Y | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs769845276, COSV100888972; called by muse, mutect2
- FAM13B | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV99221080; called by muse, mutect2, varscan2
- FAM184A | c.585A>T p.R195S | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as COSV100137491; called by muse, mutect2, varscan2
- FAM217B | c.947A>T p.K316M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV100674438; called by muse, varscan2
- FAM47C | c.2471T>A p.L824Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as COSV100792353; called by muse, mutect2, varscan2
- FAM71E1 | c.66G>T p.R22S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV100618419; called by muse, mutect2
- FAT3 | c.10744G>A p.D3582N | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99963028; called by muse, mutect2, varscan2
- FEM1C | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.216); catalogued as COSV99174352; called by muse, mutect2, varscan2
- FGA | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100120135, COSV57393927; called by muse, mutect2, varscan2
- FMN2 | c.2531C>G p.S844C | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.436); catalogued as COSV100143607, COSV100147115; called by muse, mutect2, varscan2
- FMR1 | c.1831C>A p.R611S | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as rs961588789, COSV54421419, COSV54428698; called by muse, mutect2, varscan2
- FRY | c.8554G>T p.V2852L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV100968889; called by muse, mutect2, varscan2
- FTHL17 | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV100784257; called by muse, mutect2, varscan2
- FTHL17 | c.465C>A p.N155K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV100784259; called by muse, mutect2, varscan2
- FYN | c.786T>A p.D262E | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV99991276; called by muse, mutect2, varscan2
- GABRR1 | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs1482133002, COSV101033789, COSV65619177; called by muse, mutect2, varscan2
- GAK | c.1507G>A p.V503I | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as rs777153184, COSV58504400; called by muse, mutect2, varscan2
- GCC1 | c.1086G>C p.R362S | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100365418; called by muse, mutect2, varscan2
- GFAP | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 24/91 reads (26%) | catalogued as COSV99493107; called by muse, mutect2, varscan2
- GPT | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99477459; called by muse, mutect2, varscan2
- GRIK5 | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99490184, COSV99491022; called by muse, mutect2, varscan2
- GRK7 | c.1550G>T p.W517L | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99379632; called by muse, mutect2, varscan2
- HDX | c.292T>G p.W98G | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.986); catalogued as COSV99946799; called by muse, mutect2, varscan2
- HHEX | c.509T>A p.L170Q | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99262897; called by muse, mutect2, varscan2
- HINFP | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.257); catalogued as COSV100640824; called by muse, mutect2, varscan2
- HIVEP1 | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.807); catalogued as COSV101044849; called by muse, mutect2, varscan2
- HSD17B4 | c.1901C>T p.S634F (on ENST00000414835 / NM_001199291.3; = p.S609F on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs772944749, COSV99819581; called by muse, mutect2, varscan2
- HSPA6 | c.488C>G p.A163G | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as rs781041055, COSV100553814, COSV100553971, COSV59062196; called by muse, mutect2, varscan2
- HSPG2 | c.9521C>T p.S3174L | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV101013360; called by muse, mutect2, varscan2
- HUWE1 | c.12380A>C p.Y4127S | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53357157, COSV99470997; called by muse, mutect2, varscan2
- HUWE1 | c.12379T>A p.Y4127N | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99471001; called by muse, mutect2, varscan2
- HUWE1 | c.10595C>A p.T3532N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.051); catalogued as COSV53348713; called by muse, mutect2, varscan2
- IFNA2 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV101206975; called by muse, mutect2
- IL1RAPL1 | c.1753C>A p.Q585K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV100145742; called by muse, mutect2, varscan2
- IRS4 | c.3068C>A p.S1023* | Nonsense Mutation (SNP) | VAF 35/149 reads (23%) | catalogued as COSV100929466; called by muse, mutect2, varscan2
- ITSN1 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV101180449; called by muse, mutect2, varscan2
- JMJD4 | c.1340A>G p.K447R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV100247970; called by muse, mutect2, varscan2
- KAT6A | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 44/421 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99704568; called by muse, mutect2, varscan2
- KCTD10 | c.105G>T p.K35N | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99949103; called by muse, mutect2, varscan2
- KEL | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.663); catalogued as rs566566734, COSV100786914; called by muse, mutect2, varscan2
- KIF12 | c.646G>T p.G216C (on ENST00000640217; = p.G78C on NM_138424.1) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100936056; called by muse, mutect2, varscan2
- KMT2B | c.6588G>T p.K2196N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV99719022; called by muse, mutect2, varscan2
- KMT2C | c.3743C>T p.S1248L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100068668, COSV51287239; called by muse, mutect2, varscan2
- KPNA1 | c.1499T>C p.I500T | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100724129; called by muse, mutect2
- KRT3 | c.857T>A p.F286Y | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.456); catalogued as COSV100526929; called by muse, mutect2, varscan2
- LIN28B | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.211); catalogued as COSV100558600; called by muse, mutect2, varscan2
- LRP1B | c.8725C>A p.L2909I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as COSV67190161, COSV67273748; called by muse, mutect2, varscan2
- LRRC55 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101546714; called by muse, mutect2, varscan2
- LRRTM4 | c.1286G>T p.S429I | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV69141380; called by muse, mutect2, varscan2
- LY9 | c.606T>A p.N202K | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as COSV99626325, COSV99626776; called by muse, mutect2, varscan2
- MAG | c.1173G>T p.W391C | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV100727654; called by muse, mutect2, varscan2
- MAGEA4 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52343411; called by muse, mutect2, varscan2
- MAGEE1 | c.2089A>G p.R697G | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100819322; called by muse, mutect2, varscan2
- MAP4K3 | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99810082; called by muse, mutect2, varscan2
- MC5R | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs981025616, COSV100228957; called by muse, mutect2
- MCM3AP | c.4526C>T p.A1509V | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs769709166, COSV99386572; called by muse, mutect2, varscan2
- MCTP1 | c.1617C>A p.D539E | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs1300341886, COSV100386505; called by muse, mutect2, varscan2
- MDGA2 | c.2342C>A p.A781D (on ENST00000399232 / NM_001113498.2; = p.A483D on NM_182830.4) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100636517, COSV62100368; called by muse, mutect2, varscan2
- MED1 | c.3934C>T p.H1312Y | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV100327531; called by muse, mutect2, varscan2
- MEGF6 | c.4151G>T p.G1384V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99619681; called by muse, mutect2, varscan2
- MGAT4C | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.494); catalogued as COSV100152742, COSV59832709; called by muse, mutect2, varscan2
- MPEG1 | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs763186541, COSV57091835, COSV99915110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRPS28 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.272); catalogued as COSV99398680; called by muse, mutect2, varscan2
- MRTFA | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs149542196; called by muse, mutect2, varscan2
- MS4A3 | c.587G>C p.C196S | Missense Mutation (SNP) | VAF 74/271 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV99614565; called by muse, mutect2, varscan2
- MUC16 | c.9431G>A p.W3144* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as rs1442896897, COSV101198645; called by muse, mutect2, varscan2
- MUC3A | c.7348T>A p.S2450T | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious, low confidence (0.01); catalogued as COSV100114135; called by muse, mutect2, varscan2
- MYO1G | c.2288G>T p.R763M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51853318, COSV99348541; called by muse, mutect2, varscan2
- NAA25 | c.1357G>T p.G453W | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99927352; called by muse, mutect2, varscan2
- NAP1L2 | c.1151G>C p.R384T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV100999189; called by muse, mutect2, varscan2
- NCAN | c.3289G>T p.G1097C | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99386736; called by muse, mutect2, varscan2
- NEB | c.11100T>A p.D3700E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as COSV99416718; called by muse, mutect2, varscan2
- NECTIN3 | c.1519C>A p.P507T | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV100162186; called by muse, mutect2, varscan2
- NEU3 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as COSV99579187; called by muse, mutect2, varscan2
- NHS | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV101196445; called by muse, mutect2
- NIN | c.4547C>A p.S1516Y (on ENST00000382041 / NM_182946.1; = p.S803Y on NM_016350.4) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99812193; called by muse, mutect2, varscan2
- NIPA2 | c.34A>G p.I12V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV100508770; called by muse, mutect2, varscan2
- NMUR1 | c.274C>A p.R92S | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV100531844; called by muse, mutect2, varscan2
- NRAP | c.1046C>G p.S349W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100748319; called by muse, mutect2, varscan2
- NUDT16 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100720803; called by muse, mutect2, varscan2
- NUDT16 | c.458G>C p.G153A | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100720804; called by muse, mutect2, varscan2
- OFD1 | c.989G>T p.R330I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100406767, COSV100407152; called by muse, mutect2, varscan2
- OLFM3 | c.422A>T p.K141M (on ENST00000338858 / NM_001288821.1; = p.K121M on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100129021, COSV58804054; called by muse, mutect2, varscan2
- OR10A3 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs146552050; called by muse, mutect2, varscan2
- OR1D2 | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1409837569, COSV100513875; called by muse, mutect2, varscan2
- OR2A5 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as COSV68738960; called by muse, mutect2, varscan2
- OR2C3 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs369294019; called by muse, mutect2, varscan2
- OR2F2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); catalogued as COSV101283799; called by muse, mutect2, varscan2
- OR2M5 | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs770621946, COSV100822753; called by muse, mutect2, varscan2
- OR2T12 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV100527599; called by muse, mutect2
- OR4C12 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.246); catalogued as COSV100078336; called by muse, mutect2, varscan2
- OR4D5 | c.401T>A p.L134H | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV100189789; called by muse, mutect2, varscan2
- OR4K5 | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 74/372 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV60005393; called by muse, mutect2, varscan2
- OR51I1 | c.265T>G p.F89V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100970827; called by muse, mutect2, varscan2
- OR52E8 | c.732C>A p.N244K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs1433301323, COSV101190060; called by muse, mutect2, varscan2
- OR52H1 | c.590A>G p.N197S (on ENST00000322653; = p.N203S on NM_001005289.1) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs754410738, COSV100497276; called by muse, mutect2, varscan2
- OR5AS1 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.228); catalogued as COSV100546188; called by muse, mutect2, varscan2
- OR5D16 | c.925A>T p.T309S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV101003869; called by muse, mutect2, varscan2
- OR5H2 | c.86A>T p.K29I | Missense Mutation (SNP) | VAF 181/447 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV100788664; called by muse, mutect2, varscan2
- OR6C70 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV100524352, COSV59244835; called by muse, mutect2, varscan2
- ORAI2 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 75/324 reads (23%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.04); catalogued as rs751764863, COSV62690394; called by muse, mutect2, varscan2
- OTOP1 | c.1172C>G p.S391W | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99587432; called by muse, mutect2, varscan2
- PAH | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.054); catalogued as COSV100187725; called by muse, mutect2, varscan2
- PCDH11X | c.2740C>A p.Q914K | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as COSV100009263; called by muse, mutect2, varscan2
- PCDHB8 | c.1949A>T p.E650V | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV99176201; called by muse, mutect2, varscan2
- PKHD1L1 | c.10642G>C p.D3548H | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs755813507, COSV101005601, COSV65749557; called by muse, mutect2, varscan2
- PKLR | c.1015del p.D339Tfs*2 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as CD011646, CM981562; called by mutect2, pindel
- PLCXD3 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1042533453, COSV100125376; called by muse, mutect2, varscan2
- PLG | c.836C>A p.T279K | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99804336; called by muse, mutect2, varscan2
- PLXNA4 | c.3882del p.E1295Sfs*9 | Frame Shift Del (DEL) | VAF 27/145 reads (19%) | catalogued as COSV58113888, COSV58135816; called by mutect2, pindel, varscan2
- PNLIPRP1 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 99/319 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.176); catalogued as rs140020062, COSV100724288, COSV62611909; called by muse, mutect2, varscan2
- POLA1 | c.3754C>A p.H1252N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.108); catalogued as COSV100985118; called by muse, mutect2, varscan2
- PSME4 | c.4585C>T p.H1529Y | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV101122318; called by muse, mutect2, varscan2
- RAD51AP2 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV101208299; called by muse, mutect2, varscan2
- RAPH1 | c.2755C>G p.P919A | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV99863502; called by muse, mutect2
- RBPJL | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs775667917, COSV100636921; called by muse, mutect2, varscan2
- RER1 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV56581043, COSV99992011; called by muse, mutect2, varscan2
- RET | c.2267C>G p.A756G | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM165883, COSV100392697, COSV60686616; called by muse, mutect2, varscan2
- RGN | c.94G>T p.V32L | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100282397; called by muse, mutect2, varscan2
- RGS7 | c.340T>A p.Y114N | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100465362; called by muse, mutect2, varscan2
- RIPPLY1 | c.263C>G p.T88S | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.283); catalogued as COSV99343606; called by muse, mutect2, varscan2
- RLIM | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV100222869; called by muse, mutect2, varscan2
- RNF150 | c.901C>A p.H301N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153041; called by muse, mutect2, varscan2
- RNF182 | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.031); catalogued as COSV101337851; called by muse, mutect2
- RNF19A | c.2405A>G p.N802S | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs567250945, COSV100347461; called by muse, mutect2, varscan2
- RTL3 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs769439902, COSV100329596; called by muse, mutect2, varscan2
- RTL9 | c.1993G>T p.G665W | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101511646; called by muse, mutect2, varscan2
- RUSF1 | c.903G>C p.Q301H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as COSV100393047; called by muse, mutect2, varscan2
- RYR3 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV66784355; called by muse, mutect2
- RYR3 | c.4036G>A p.G1346R | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309424472, COSV66780694; called by muse, mutect2, varscan2
- SCGB2A2 | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99929283; called by muse, mutect2, varscan2
- SCN1A | c.698T>A p.L233Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as CD119312, CM113277, COSV100319603, COSV57686485; called by muse, mutect2, varscan2
- SEC14L3 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.343); catalogued as COSV99307005; called by muse, mutect2, varscan2
- SELENOM | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100294084; called by muse, mutect2, varscan2
- SFMBT2 | c.1672G>T p.G558C | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100738568; called by muse, mutect2, varscan2
- SFRP4 | c.635A>G p.N212S | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.245); catalogued as COSV101460875; called by muse, mutect2, varscan2
- SGCD | c.454G>C p.D152H (on ENST00000435422 / NM_001128209.2; = p.D153H on NM_000337.5) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV100549052, COSV61910331; called by mutect2, varscan2
- SHPRH | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs371743858; called by muse, mutect2, varscan2
- SIGLEC8 | c.683T>A p.L228* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as COSV100367177; called by muse, mutect2, varscan2
- SIM1 | c.1634C>A p.S545* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as COSV99492073; called by muse, mutect2, varscan2
- SLC16A7 | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.289); catalogued as rs777391165, COSV99676251; called by muse, mutect2, varscan2
- SLC25A25 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1258880715, COSV100895728; called by muse, mutect2
- SLC7A13 | c.567T>A p.N189K | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52536593, COSV99878597; called by muse, mutect2, varscan2
- SLC9C1 | c.1917C>G p.I639M | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV59887200, COSV99997480; called by muse, mutect2, varscan2
- SLCO1B1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs139907543, COSV57018900; called by muse, mutect2, varscan2
- SNCAIP | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV99747579; called by muse, mutect2, varscan2
- SNPH | c.1046C>A p.P349Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as COSV100378020; called by muse, mutect2, varscan2
- SORCS1 | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV99544099; called by muse, mutect2, varscan2
- SORCS1 | c.2346G>T p.R782S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV99544100; called by muse, mutect2, varscan2
- SPEF2 | c.3579G>T p.L1193F | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100606584; called by muse, mutect2, varscan2
- SPTA1 | c.443T>A p.L148Q | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100934196; called by muse, mutect2, varscan2
- SPTBN4 | c.7597G>A p.A2533T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.37); catalogued as rs769146610, COSV52541175; called by muse, mutect2, varscan2
- SPTLC3 | c.347G>C p.R116T | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100982956; called by muse, mutect2, varscan2
- SRRM2 | c.5021C>T p.S1674L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs750513208, COSV100070394; called by muse, mutect2, varscan2
- STEAP1 | c.116A>T p.K39I | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.08); catalogued as COSV51880854, COSV99787561; called by muse, mutect2
- SV2C | c.1888G>T p.G630C | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as COSV100455795, COSV100456897; called by muse, mutect2, varscan2
- TAF1L | c.4093C>T p.P1365S | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV54264460; called by muse, mutect2, varscan2
- TAF4 | c.2881C>G p.Q961E | Missense Mutation (SNP) | VAF 101/374 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.191); catalogued as COSV99433630; called by muse, mutect2, varscan2
- TBC1D8B | c.3172A>G p.T1058A | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV52179270, COSV99343981; called by muse, mutect2, varscan2
- TBCCD1 | c.1471C>G p.Q491E | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV100111839; called by muse, mutect2
- TBCEL | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99412004; called by muse, mutect2, varscan2
- TBX19 | c.99A>T p.K33N | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100892336, COSV63197590; called by muse, mutect2, varscan2
- TCEAL5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101013099, COSV65503052; called by muse, mutect2, varscan2
- TEC | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.423); catalogued as COSV101202566; called by muse, mutect2
- TENM4 | c.7916G>A p.R2639Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs775067963, COSV53659215; called by muse, mutect2, varscan2
- TET1 | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.541); catalogued as COSV101017751, COSV101017885; called by muse, mutect2, varscan2
- TEX2 | c.3054C>G p.N1018K (on ENST00000583097 / NM_001288733.2; = p.N1025K on NM_018469.5) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99366862; called by muse, mutect2, varscan2
- TEX35 | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.836); catalogued as rs759986091, COSV99274123; called by muse, mutect2, varscan2
- THSD7B | c.2792A>G p.Y931C | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.754); catalogued as COSV99745971; called by muse, mutect2, varscan2
- TIGIT | c.709T>A p.C237S | Missense Mutation (SNP) | VAF 78/379 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs747792969, COSV101047966; called by muse, mutect2, varscan2
- TLR7 | c.805C>G p.P269A | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV101027767, COSV66124327; called by muse, mutect2, varscan2
- TMEM130 | c.350G>A p.C117Y | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1554400079, COSV59559342, COSV59559694; called by muse, mutect2, varscan2
- TMPRSS7 | c.2258A>T p.E753V (on ENST00000452346; = p.E627V on NM_001042575.2) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101340091; called by muse, mutect2, varscan2
- TMTC1 | c.1745C>T p.A582V (on ENST00000539277 / NM_001193451.2; = p.A474V on NM_175861.3) | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV99758993; called by muse, mutect2, varscan2
- TNIK | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as rs758624618, COSV99455687; called by muse, mutect2
- TNS1 | c.46G>T p.V16L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV99410073; called by muse, mutect2, varscan2
- TRIM17 | c.1322A>C p.H441P | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99488166; called by muse, mutect2, varscan2
- TRIM51 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV99792247; called by muse, mutect2, varscan2
- TRIO | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV100710028; called by muse, mutect2, varscan2
- TRRAP | c.7078G>A p.D2360N (on ENST00000359863 / NM_001244580.1; = p.D2342N on NM_003496.3) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV100722144; called by muse, mutect2, varscan2
- TSPAN6 | c.521C>G p.P174R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100885759; called by muse, mutect2, varscan2
- TTN | c.72043C>A p.H24015N (on ENST00000591111; = p.H16591N on NM_003319.4) | Missense Mutation (SNP) | VAF 53/298 reads (18%) | PolyPhen benign (0.003); catalogued as COSV100599095, COSV60335403; called by muse, mutect2, varscan2
- TTN | c.72042C>A p.C24014* (on ENST00000591111; = p.C16590* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 54/301 reads (18%) | catalogued as COSV100599098; called by muse, mutect2, varscan2
- TTN | c.51866G>C p.R17289T (on ENST00000591111; = p.R9865T on NM_003319.4) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | PolyPhen probably damaging (0.996); catalogued as COSV100599100; called by muse, mutect2, varscan2
- TTN | c.25004T>A p.I8335K (on ENST00000591111; = p.I7408K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | PolyPhen benign (0.029); catalogued as COSV100599102; called by muse, mutect2, varscan2
- TTN | c.10024G>A p.V3342I (on ENST00000591111; = p.V3296I on NM_003319.4) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | PolyPhen benign (0.003); catalogued as rs727503679, COSV100599104; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TTN | c.7525G>T p.A2509S (on ENST00000591111; = p.A2463S on NM_003319.4) | Missense Mutation (SNP) | VAF 30/112 reads (27%) | PolyPhen possibly damaging (0.819); catalogued as COSV100599105; called by muse, mutect2
- UFL1 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV65150242; called by muse, mutect2, varscan2
- UGT3A2 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); catalogued as COSV56930645, COSV99236064; called by muse, mutect2
- UNC13C | c.6169G>T p.G2057* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV99512994; called by muse, mutect2, varscan2
- UNC13C | c.6170G>T p.G2057V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); catalogued as COSV52865133, COSV99512997; called by muse, mutect2, varscan2
- USH2A | c.4609G>C p.V1537L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100230776; called by muse, mutect2, varscan2
- USP25 | c.902G>C p.G301A | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99583314; called by muse, mutect2, varscan2
- VPS13B | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.678); catalogued as rs886062535, COSV62024201; ClinVar: uncertain significance; called by muse, mutect2
- VPS45 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV100964866; called by muse, mutect2, varscan2
- XIRP2 | c.9712A>T p.R3238W (on ENST00000628543; = p.R3413W on NM_152381.6) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV54694126; called by muse, mutect2, varscan2
- ZBTB21 | c.2347A>C p.T783P | Missense Mutation (SNP) | VAF 73/331 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100176962; called by muse, mutect2, varscan2
- ZCCHC12 | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); catalogued as COSV100038437; called by muse, mutect2, varscan2
- ZDHHC2 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100024614; called by muse, mutect2, varscan2
- ZFHX3 | c.4042C>T p.P1348S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV99195625; called by muse, mutect2, varscan2
- ZFHX4 | c.3188T>A p.V1063E | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV99258435; called by muse, mutect2, varscan2
- ZFHX4 | c.10292C>A p.P3431H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99258444; called by muse, mutect2, varscan2
- ZNF572 | c.1175G>A p.S392N | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs1400605564, COSV100073855, COSV60001228; called by muse, mutect2, varscan2
- ZNF587 | c.1517C>G p.A506G | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as rs369252362, COSV100299343; called by muse, mutect2, varscan2
- ZNF667 | c.659G>C p.R220T | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV99410126; called by muse, mutect2, varscan2
- ACTRT1 | c.219del p.I74Lfs*6 | Frame Shift Del (DEL) | VAF 59/250 reads (24%) | called by mutect2, pindel, varscan2
- ATRX | c.3076del p.C1026Vfs*7 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by pindel, varscan2
- CDKN2A | c.465del p.D156Ifs*37 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- CT45A3 | c.514T>A p.C172S | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2
- FCRL4 | c.1360+2del p.X454_splice | Splice Site (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.6727del p.R2243Afs*239 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- IGKV3D-20 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- INAVA | c.898del p.T300Pfs*105 | Frame Shift Del (DEL) | VAF 31/152 reads (20%) | called by mutect2, pindel, varscan2
- IWS1 | c.1289del p.G430Afs*7 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- MOG | c.312del p.I105Lfs*6 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel, varscan2
- MS4A12 | c.687_689del p.T231del | In Frame Del (DEL) | VAF 12/56 reads (21%) | called by pindel, varscan2
- PLK4 | c.1737_1738dup p.W580Yfs*9 | Frame Shift Ins (INS) | VAF 17/99 reads (17%) | called by mutect2, pindel, varscan2
- RFWD3 | c.1270del p.C424Afs*36 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- SCAF11 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.591); called by muse, mutect2
- SLC33A1 | c.83del p.G28Vfs*35 | Frame Shift Del (DEL) | VAF 29/84 reads (35%) | called by mutect2, pindel, varscan2
- SLC6A3 | c.1506del p.Q503Sfs*9 | Frame Shift Del (DEL) | VAF 57/177 reads (32%) | called by mutect2, pindel, varscan2
- SLC8A3 | c.2244del p.T749Qfs*76 (on ENST00000381269 / NM_183002.3; = p.T747Qfs*76 on NM_033262.4) | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- SPTBN4 | c.3511G>C p.D1171H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); called by muse, mutect2
- SUSD2 | c.1893del p.X631_splice | Splice Site (DEL) | VAF 36/112 reads (32%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2408A>T p.Y803F | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTSL3 | c.3879C>T p.I1293= | Silent (SNP) | VAF 77/318 reads (24%) | catalogued as COSV99717440; called by muse, mutect2, varscan2
- ADRM1 | c.1083G>A p.L361= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV53373013; called by muse, mutect2, varscan2
- ADRM1 | c.1182G>A p.T394= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs374034164; called by muse, mutect2
- AGAP3 | c.2430G>T p.V810= (on ENST00000622464; = p.V846= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV99880771; called by muse, mutect2, varscan2
- ARHGEF26 | c.1263C>T p.L421= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100726424; called by muse, mutect2
- ASPM | c.5400A>G p.Q1800= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as COSV99659780, COSV99660380; called by muse, mutect2, varscan2
- BICD1 | c.1915C>T p.L639= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as COSV55681204; called by muse, mutect2, varscan2
- C5AR2 | c.708A>T p.T236= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99953684; called by muse, mutect2, varscan2
- CACNA1F | c.2499G>T p.L833= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100544480; called by muse, varscan2
- CD248 | c.741G>C p.V247= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100256506; called by mutect2, varscan2
- CDYL2 | c.252G>C p.P84= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV101629519, COSV73647999; called by muse, mutect2, varscan2
- CHM | c.1728T>C p.S576= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV100753082; called by muse, mutect2, varscan2
- COBLL1 | c.1245T>C p.D415= (on ENST00000392717; = p.D377= on NM_014900.5) | Silent (SNP) | VAF 106/419 reads (25%) | catalogued as COSV99527480; called by muse, mutect2, varscan2
- COL25A1 | c.1755T>C p.Y585= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV101211268; called by muse, mutect2, varscan2
- CSMD3 | c.3738G>A p.T1246= (on ENST00000297405 / NM_001363185.1; = p.T1142= on NM_052900.3) | Silent (SNP) | VAF 109/223 reads (49%) | catalogued as rs1395803496, COSV52117937, COSV52310072; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYP3A5 | c.882G>A p.E294= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs774266940, COSV99769566; called by muse, mutect2, varscan2
- DCC | c.3237A>T p.P1079= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV101472490; called by muse, mutect2, varscan2
- DHCR24 | c.543C>A p.G181= | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as rs1474779415, COSV100987784; called by muse, mutect2, varscan2
- DHX16 | c.1422G>T p.G474= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV100905141; called by muse, mutect2, varscan2
- DNAH9 | c.11019G>A p.E3673= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs767506464, COSV99304655; called by muse, mutect2, varscan2
- EGFL6 | c.393G>C p.T131= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs184273053, COSV100768708; called by muse, mutect2, varscan2
- FAM47B | c.1560C>A p.V520= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV100264130, COSV61453513; called by muse, mutect2, varscan2
- FAM47C | c.2344C>A p.R782= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV100792352; called by muse, mutect2, varscan2
- FOXN4 | c.801G>T p.L267= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100142087; called by muse, mutect2, varscan2
- GGA3 | c.246C>T p.N82= | Silent (SNP) | VAF 69/224 reads (31%) | catalogued as rs200542166; called by muse, mutect2, varscan2
- GHR | c.1707A>G p.T569= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1461806137, COSV100050056; called by muse, mutect2, varscan2
- GMEB1 | c.1587C>T p.D529= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV99603019; called by muse, mutect2, varscan2
- GPKOW | c.381G>A p.T127= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs1224227051, COSV99332521; called by muse, mutect2, varscan2
- H1-2 | c.75C>G p.A25= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100642262; called by muse, mutect2, varscan2
- HSPG2 | c.9318C>T p.L3106= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV101013361; called by muse, mutect2, varscan2
- HYDIN | c.15153C>A p.T5051= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV101124947; called by muse, mutect2, varscan2
- IGF1R | c.2124G>A p.E708= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV51416169, COSV99149632; called by muse, mutect2, varscan2
- IGF1R | c.3066G>A p.V1022= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV99149641; called by muse, mutect2, varscan2
- INTS10 | c.1854A>G p.Q618= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs770468173, COSV101208653; called by muse, mutect2
- KCNQ5 | c.609T>C p.C203= | Silent (SNP) | VAF 53/164 reads (32%) | catalogued as COSV100571529; called by muse, mutect2, varscan2
- KMT5B | c.1128C>T p.V376= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV100069863; called by muse, mutect2, varscan2
- LY75 | c.4827G>A p.Q1609= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99716123; called by muse, mutect2, varscan2
- MAGEE1 | c.1119T>A p.S373= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100819321; called by muse, mutect2, varscan2
- MYH11 | c.1794G>A p.P598= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs749272388, COSV100258017, COSV55560252; ClinVar: likely benign; called by muse, mutect2, varscan2
- NNT | c.2289G>A p.L763= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99238520; called by muse, mutect2
- NOX5 | c.1209G>C p.L403= | Silent (SNP) | VAF 55/273 reads (20%) | catalogued as COSV99533429; called by muse, mutect2, varscan2
- OOEP | c.348T>C p.F116= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV100949794; called by muse, mutect2, varscan2
- OR11H6 | c.702A>G p.G234= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100209736; called by muse, mutect2, varscan2
- OR4K15 | c.324C>T p.D108= (on ENST00000305051; = p.D84= on NM_001005486.1) | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV100520994; called by muse, mutect2
- OR52K1 | c.456C>T p.A152= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV100297593; called by muse, mutect2, varscan2
- OR5J2 | c.741T>C p.A247= | Silent (SNP) | VAF 45/154 reads (29%) | catalogued as COSV100398929; called by muse, mutect2, varscan2
- OR9I1 | c.912C>G p.V304= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as rs368868026, COSV56925654, COSV56925909; called by muse, mutect2, varscan2
- PADI3 | c.1350C>A p.L450= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV100968417; called by muse, mutect2, varscan2
- PCDH19 | c.2163C>T p.I721= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99719220; called by muse, mutect2, varscan2
- PCDH7 | c.1170C>G p.R390= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100687723; called by muse, mutect2, varscan2
- PCDHB9 | c.1503C>A p.A501= | Silent (SNP) | VAF 166/345 reads (48%) | called by muse, mutect2, varscan2
- PCIF1 | c.1752C>T p.F584= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV100532731; called by muse, mutect2, varscan2
- PCSK1 | c.2052A>T p.S684= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100226911; called by muse, mutect2
- PDE6B | c.1023C>T p.A341= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV99727043; called by muse, mutect2, varscan2
- PGLYRP2 | c.1356C>T p.G452= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1338707825, COSV99483820; called by muse, mutect2, varscan2
- PIAS3 | c.411C>T p.V137= | Silent (SNP) | VAF 22/167 reads (13%) | catalogued as COSV100992657; called by muse, mutect2, varscan2
- PLXNA4 | c.4026C>A p.G1342= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100322998; called by muse, mutect2, varscan2
- PPP2R3A | c.2076C>T p.S692= | Silent (SNP) | VAF 38/155 reads (25%) | catalogued as COSV99386593; called by muse, mutect2, varscan2
- PRKDC | c.6216G>T p.R2072= | Silent (SNP) | VAF 60/381 reads (16%) | catalogued as COSV100038939; called by muse, mutect2, varscan2
- PTH2R | c.588C>G p.V196= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV99782189; called by muse, mutect2, varscan2
- PXDNL | c.3939A>G p.Q1313= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV100682191; called by muse, mutect2, varscan2
- RIMBP2 | c.1236A>T p.L412= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99898678; called by muse, mutect2, varscan2
- SFMBT2 | c.1671G>T p.P557= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs200717836, COSV62808909; called by muse, mutect2, varscan2
- SIRPG | c.975G>C p.V325= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as COSV99403523; called by muse, mutect2, varscan2
- SLC13A4 | c.1710C>A p.V570= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100818817; called by muse, mutect2, varscan2
- SLITRK2 | c.621G>A p.G207= | Silent (SNP) | VAF 50/191 reads (26%) | catalogued as COSV100157428, COSV59424546; called by muse, mutect2, varscan2
- SOX6 | c.2433C>T p.P811= (on ENST00000528429 / NM_001145819.2; = p.P784= on NM_017508.3) | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV100321442; called by muse, mutect2, varscan2
- SPN | c.786G>C p.V262= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV100788717; called by muse, mutect2, varscan2
- ST8SIA1 | c.525T>A p.T175= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV99682845; called by muse, mutect2, varscan2
- TENM4 | c.7915C>A p.R2639= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV53620207, COSV99572138; called by muse, mutect2, varscan2
- TRIM11 | c.78G>C p.P26= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV52858205, COSV99488164; called by mutect2, varscan2
- TRIM56 | c.1347C>G p.P449= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs754501748, COSV100047056; called by muse, varscan2
- TRPC7 | c.339C>G p.A113= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV100725551; called by muse, mutect2, varscan2
- UHRF1BP1L | c.4167G>A p.L1389= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV54440480; called by muse, mutect2, varscan2
- UNC13A | c.1899C>A p.I633= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV99407425; called by muse, mutect2, varscan2
- USF3 | c.1608T>C p.A536= | Silent (SNP) | VAF 36/208 reads (17%) | catalogued as COSV100324861; called by muse, mutect2, varscan2
- USH2A | c.13050A>G p.T4350= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV100230774; called by muse, mutect2, varscan2
- VBP1 | c.513C>A p.T171= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV99660740; called by muse, mutect2, varscan2
- XIRP2 | c.6858G>A p.K2286= (on ENST00000628543; = p.K2461= on NM_152381.6) | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs775965854, COSV54687451, COSV54730308; called by muse, mutect2, varscan2
- ZNF236 | c.72G>C p.A24= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV53495939, COSV99469480; called by muse, mutect2, varscan2
- ZNF586 | c.441A>G p.Q147= | Silent (SNP) | VAF 61/156 reads (39%) | catalogued as COSV101197622; called by muse, mutect2, varscan2
- ZNF781 | c.651C>G p.L217= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs150275573; called by muse, mutect2, varscan2
- ZXDB | c.306C>G p.G102= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100885814; called by muse, varscan2
- AKAP13 | c.4800-2174A>T | Intron (SNP) | VAF 46/193 reads (24%) | catalogued as COSV100773228; called by muse, mutect2, varscan2
- CBLIF | c.*2G>T | 3'UTR (SNP) | VAF 21/71 reads (30%) | catalogued as COSV99950664, COSV99950786; called by muse, mutect2, varscan2
- CDKN1B | c.*149A>G | 3'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as rs765213102, COSV99963836; called by muse, varscan2
- GDF5 | c.-398+629G>A | Intron (SNP) | VAF 19/43 reads (44%) | catalogued as COSV100698787; called by muse, mutect2, varscan2
- KIF1B | c.2115+6101G>T | Intron (SNP) | VAF 40/89 reads (45%) | catalogued as COSV99822701; called by muse, mutect2, varscan2
- KIF2B | c.-1C>T | 5'UTR (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99274847, COSV99276271; called by muse, mutect2, varscan2
- KLHL4 | c.*2853G>A | 3'UTR (SNP) | VAF 14/64 reads (22%) | catalogued as rs1179599244, COSV100909258; called by muse, mutect2, varscan2
- MIR508 | n.66G>C | RNA (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- PKD1L2 | n.2963C>A | RNA (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- SLC17A3 | c.304-140C>A | Intron (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100399103; called by muse, mutect2, varscan2
- YY1AP1 | c.927-23G>C | Intron (SNP) | VAF 16/77 reads (21%) | catalogued as COSV99803538, COSV99803589; called by muse, mutect2, varscan2
